Somatic mutation profile of tumor specimen TCGA-IN-A6RP-01A (aliquot TCGA-IN-A6RP-01A-21D-A33T-08) from TCGA case TCGA-IN-A6RP, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Cardia, NOS; Tumor grade: G3; Age at diagnosis: 63.7 years (23,282 days).
Specimen TCGA-IN-A6RP-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 53a75b3b-a65e-4834-9402-21aa3767e6b7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-IN-A6RP-10A (Blood Derived Normal), aliquot TCGA-IN-A6RP-10A-01D-A33W-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4f7901ec-7da5-4b9d-adc5-44a2ea5fd336

The open-access MAF lists 165 somatic variants for this specimen: 129 protein-altering or splice-affecting, 31 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 108, Silent 31, Nonsense Mutation 14, Frame Shift Ins 3, RNA 3, Intron 2, In Frame Del 2, Frame Shift Del 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.4666dup p.T1556Nfs*3 | Frame Shift Ins (INS) | VAF 30/81 reads (37%) | catalogued as rs587783031, COSV57351096; ClinVar: uncertain significance / pathogenic; called by mutect2, pindel, varscan2
- ECEL1 | c.1210C>T p.R404C | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs532757890, CM146136, COSV100458474; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- SMARCA4 | c.3694G>A p.G1232S | Missense Mutation (SNP) | VAF 52/158 reads (33%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.797); catalogued as COSV60785813, COSV60799159; called by muse, mutect2, varscan2
- TP53 | c.742C>T p.R248W | Missense Mutation (SNP) | VAF 15/90 reads (17%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121912651, CM010465, CM900211, COSV52662035, COSV52797251, COSV53097881; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ACTRT2 | c.62G>A p.C21Y | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.853); catalogued as rs1243794202, COSV101007505; called by muse, mutect2, varscan2
- ADA2 | c.25C>T p.R9W | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as rs753994372, COSV99375745; called by muse, mutect2, varscan2
- AFF4 | c.1763C>A p.T588N | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.987); catalogued as COSV99534616; called by muse, mutect2
- AQP3 | c.487G>C p.D163H | Missense Mutation (SNP) | VAF 19/234 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99955497; called by muse, mutect2
- ATR | c.1903C>T p.R635* | Nonsense Mutation (SNP) | VAF 23/81 reads (28%) | catalogued as rs1378333855, COSV63386547; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BOD1L1 | c.7789C>T p.P2597S | Missense Mutation (SNP) | VAF 28/58 reads (48%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.006); catalogued as COSV99238459; called by muse, mutect2, varscan2
- BRCA2 | c.3344C>T p.S1115F | Missense Mutation (SNP) | VAF 28/96 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs879255448, COSV101203959; called by muse, mutect2, varscan2
- BTNL2 | c.238G>A p.G80R | Missense Mutation (SNP) | VAF 26/177 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV100895981; called by muse, mutect2, varscan2
- CA5A | c.213G>T p.W71C | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.952); catalogued as COSV99990412; called by muse, mutect2, varscan2
- CARMIL3 | c.3572G>A p.R1191Q | Missense Mutation (SNP) | VAF 44/180 reads (24%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.968); catalogued as rs1453958020, COSV100549274, COSV100549339; called by muse, mutect2, varscan2
- CBLC | c.931G>A p.D311N | Missense Mutation (SNP) | VAF 77/232 reads (33%) | SIFT tolerated (0.26); PolyPhen benign (0.063); catalogued as rs780714860, COSV99541844; called by muse, mutect2, varscan2
- CCDC6 | c.1280C>T p.T427M | Missense Mutation (SNP) | VAF 27/55 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as COSV99569168; called by muse, mutect2, varscan2
- CEP192 | c.4661G>A p.R1554Q | Missense Mutation (SNP) | VAF 13/156 reads (8%) | SIFT tolerated (0.21); PolyPhen benign (0.139); catalogued as rs538215951, COSV100380618; called by muse, mutect2
- CILK1 | c.443G>A p.R148Q | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.924); catalogued as rs778947062, COSV100607527; called by muse, mutect2, varscan2
- CLSTN3 | c.452G>A p.R151H | Missense Mutation (SNP) | VAF 33/109 reads (30%) | SIFT tolerated (0.2); PolyPhen benign (0.061); catalogued as rs1275589409, COSV56934538; called by muse, mutect2, varscan2
- CNTNAP5 | c.1151C>G p.P384R | Missense Mutation (SNP) | VAF 30/99 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.845); catalogued as COSV101443078, COSV70483254; called by muse, mutect2, varscan2
- COL11A1 | c.4642A>T p.I1548F | Missense Mutation (SNP) | VAF 22/84 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.386); catalogued as COSV100615272; called by muse, mutect2, varscan2
- CPSF1 | c.2623G>T p.E875* | Nonsense Mutation (SNP) | VAF 9/36 reads (25%) | catalogued as COSV100450218; called by muse, varscan2
- CSMD3 | c.1593A>C p.E531D (on ENST00000297405 / NM_001363185.1; = p.E427D on NM_052900.3) | Missense Mutation (SNP) | VAF 42/114 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.075); catalogued as COSV52105113, COSV52338075; called by muse, mutect2, varscan2
- CTNNA2 | c.2290G>T p.D764Y | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV58157663; called by muse, mutect2, varscan2
- CYP2E1 | c.1010G>A p.R337Q | Missense Mutation (SNP) | VAF 37/82 reads (45%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.469); catalogued as rs759707874, COSV53314124, COSV53314934; called by muse, mutect2, varscan2
- DLGAP1 | c.2410C>T p.R804* | Nonsense Mutation (SNP) | VAF 15/131 reads (11%) | catalogued as COSV59820622; called by muse, mutect2, varscan2
- DLX5 | c.413G>A p.R138H | Missense Mutation (SNP) | VAF 14/128 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56034475; called by muse, mutect2, varscan2
- DMBT1 | c.193C>T p.P65S | Missense Mutation (SNP) | VAF 7/159 reads (4%) | SIFT tolerated (0.16); PolyPhen benign (0.088); catalogued as COSV100352194; called by muse, mutect2
- DNAH2 | c.6349_6351del p.X2117_splice | Splice Site (DEL) | VAF 4/46 reads (9%) | catalogued as rs1429947149; called by mutect2, pindel
- DUSP6 | c.581C>T p.S194L | Missense Mutation (SNP) | VAF 24/106 reads (23%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.722); catalogued as rs1052458627, COSV99683960; called by muse, mutect2, varscan2
- DUSP9 | c.508G>A p.D170N | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.044); catalogued as rs781935257, COSV100720066; called by muse, mutect2
- EDIL3 | c.31G>T p.V11F | Missense Mutation (SNP) | VAF 28/71 reads (39%) | SIFT tolerated (0.11); PolyPhen benign (0.009); catalogued as COSV99674883; called by muse, mutect2, varscan2
- EIF4G1 | c.1210C>T p.L404F (on ENST00000346169 / NM_198241.3; = p.L208F on NM_004953.5) | Missense Mutation (SNP) | VAF 59/327 reads (18%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.979); catalogued as rs778666618, COSV100071502; called by muse, mutect2, varscan2
- ELAPOR2 | c.3055G>T p.V1019F (on ENST00000450689 / NM_001142749.3; = p.V852F on NM_152748.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 4/52 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs867130605, COSV99788231, COSV99789536; called by muse, mutect2
- ENPEP | c.47C>T p.T16M | Missense Mutation (SNP) | VAF 13/137 reads (9%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.373); catalogued as rs1282484926, COSV54454016; called by muse, mutect2, varscan2
- EPB41L3 | c.1585C>T p.R529C | Missense Mutation (SNP) | VAF 23/133 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.642); catalogued as rs150384501; called by muse, mutect2, varscan2
- EPHA6 | c.3155C>T p.P1052L | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT deleterious (0.03); PolyPhen benign (0.284); catalogued as rs778168979, COSV67558533; called by muse, mutect2, varscan2
- EXD1 | c.1063T>A p.L355I | Missense Mutation (SNP) | VAF 15/155 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.088); catalogued as COSV100153496; called by muse, mutect2, varscan2
- FHOD3 | c.4021C>T p.R1341* (on ENST00000359247 / NM_001281739.3; = p.R1358* on NM_025135.5) | Nonsense Mutation (SNP) | VAF 8/9 reads (89%) | catalogued as COSV57190192; called by muse, mutect2, varscan2
- FLRT2 | c.637G>A p.G213R | Missense Mutation (SNP) | VAF 43/125 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs926591443, COSV58147960; called by muse, mutect2, varscan2
- FOSB | c.400C>T p.P134S | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT tolerated, low confidence (0.1); PolyPhen probably damaging (0.992); catalogued as COSV100798691; called by muse, mutect2
- GABRB1 | c.651G>C p.K217N | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT tolerated (0.16); PolyPhen benign (0.011); catalogued as COSV55000364, COSV99780270; called by muse, mutect2, varscan2
- GP2 | c.1384G>A p.E462K (on ENST00000381362 / NM_001007240.3; = p.E459K on NM_001502.4) | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100221273; called by muse, mutect2, varscan2
- GPR55 | c.632G>A p.R211H | Missense Mutation (SNP) | VAF 7/78 reads (9%) | SIFT tolerated (0.74); PolyPhen benign (0.001); catalogued as rs766293332, COSV101235720; called by muse, mutect2
- H2BC17 | c.65C>G p.A22G | Missense Mutation (SNP) | VAF 10/102 reads (10%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.007); catalogued as COSV100377480, COSV58151903; called by muse, mutect2
- HSPA8 | c.1494G>C p.E498D | Missense Mutation (SNP) | VAF 33/91 reads (36%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.135); catalogued as COSV99914216, COSV99914285; called by muse, mutect2, varscan2
- HYDIN | c.13504G>A p.E4502K | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs1457794827, COSV101124896; called by mutect2, varscan2
- IFT172 | c.3445G>T p.A1149S | Missense Mutation (SNP) | VAF 14/78 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1235174997, COSV99561877; called by muse, mutect2, varscan2
- IGHG2 | c.221G>C p.S74T | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.416); catalogued as rs1284380144; called by muse, mutect2, varscan2
- IGLV3-10 | c.159G>C p.W53C | Missense Mutation (SNP) | VAF 35/112 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs368412336; called by muse, mutect2, varscan2
- KCNA3 | c.1244C>T p.A415V | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV63901969; called by muse, mutect2, varscan2
- KIF21B | c.1814G>A p.R605H | Missense Mutation (SNP) | VAF 10/120 reads (8%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs147761216; called by muse, mutect2
- KRTAP10-1 | c.427G>A p.V143M | Missense Mutation (SNP) | VAF 18/160 reads (11%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.961); catalogued as COSV100552036; called by muse, mutect2, varscan2
- LAMA2 | c.201C>A p.C67* | Nonsense Mutation (SNP) | VAF 7/62 reads (11%) | catalogued as COSV101370114; called by mutect2, varscan2
- LRP5 | c.3535C>T p.R1179C | Missense Mutation (SNP) | VAF 21/144 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs780585577, COSV99591468; called by muse, mutect2, varscan2
- ME3 | c.1297C>T p.H433Y | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.426); catalogued as COSV100660873; called by muse, mutect2, varscan2
- METTL4 | c.377C>T p.S126F | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV99859452; called by muse, mutect2, varscan2
- MINAR1 | c.2201G>A p.R734H | Missense Mutation (SNP) | VAF 12/71 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as rs140205068; called by muse, mutect2, varscan2
- MISP | c.1051G>A p.V351M | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as rs751601521, COSV99296610; called by muse, mutect2, varscan2
- MON1B | c.446C>T p.A149V | Missense Mutation (SNP) | VAF 20/67 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.644); catalogued as rs200826983; called by muse, mutect2, varscan2
- MRPL47 | c.742A>C p.S248R | Missense Mutation (SNP) | VAF 13/115 reads (11%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.779); catalogued as COSV99372855; called by muse, mutect2, varscan2
- MUC16 | c.12562C>A p.P4188T | Missense Mutation (SNP) | VAF 10/74 reads (14%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.026); catalogued as COSV67495463; called by muse, mutect2, varscan2
- MYADM | c.409G>A p.A137T | Missense Mutation (SNP) | VAF 35/115 reads (30%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.59); catalogued as rs1246716963, COSV61240121; called by muse, mutect2, varscan2
- MYCT1 | c.295G>T p.A99S | Missense Mutation (SNP) | VAF 6/86 reads (7%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.96); catalogued as COSV100924030; called by muse, mutect2
- MYO3A | c.3506T>C p.F1169S | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT tolerated (0.64); PolyPhen benign (0.009); catalogued as COSV99778486; called by muse, mutect2
- NBEA | c.5128G>A p.E1710K | Missense Mutation (SNP) | VAF 14/71 reads (20%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.009); catalogued as rs561239166, COSV59766532; called by muse, mutect2, varscan2
- NEO1 | c.2680C>T p.R894* | Nonsense Mutation (SNP) | VAF 7/59 reads (12%) | catalogued as COSV99981319; called by muse, mutect2, varscan2
- NFIB | c.1153C>T p.P385S | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.099); catalogued as rs1260961300, COSV101101191; called by muse, mutect2, varscan2
- NTF3 | c.721C>T p.R241W | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58417235; called by muse, mutect2, varscan2
- OR52E8 | c.761T>G p.L254* | Nonsense Mutation (SNP) | VAF 4/82 reads (5%) | catalogued as COSV101190009; called by muse, mutect2
- OR6T1 | c.764C>A p.S255Y | Missense Mutation (SNP) | VAF 23/99 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.95); catalogued as COSV58305873, COSV58308619; called by muse, mutect2, varscan2
- OR8J3 | c.575C>T p.T192I | Missense Mutation (SNP) | VAF 12/89 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.58); catalogued as COSV100040564, COSV56881866; called by muse, mutect2, varscan2
- PACS2 | c.1693C>T p.R565W | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.668); catalogued as rs782038571, COSV100330611, COSV57655351; called by muse, mutect2, varscan2
- PCDHGB1 | c.1684G>A p.A562T | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT tolerated (0.23); PolyPhen benign (0.041); catalogued as rs995541250, COSV53974235; called by muse, mutect2, varscan2
- PCDHGB3 | c.17G>T p.G6V | Missense Mutation (SNP) | VAF 20/45 reads (44%) | SIFT tolerated (0.12); PolyPhen benign (0.017); catalogued as COSV99531436; called by muse, mutect2, varscan2
- PDE7A | c.653C>T p.A218V (on ENST00000401827 / NM_001242318.3; = p.A192V on NM_002603.4) | Missense Mutation (SNP) | VAF 50/153 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs995189628, COSV101052603; called by muse, mutect2, varscan2
- PGAP1 | c.1868G>T p.C623F | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100698019; called by muse, mutect2, varscan2
- PIK3R5 | c.776C>T p.A259V | Missense Mutation (SNP) | VAF 52/117 reads (44%) | SIFT tolerated (0.27); PolyPhen benign (0.083); catalogued as rs369083136; called by muse, mutect2, varscan2
- PLXNA2 | c.2422C>T p.R808W | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs373107594; called by muse, mutect2, varscan2
- PNPLA7 | c.2914G>A p.E972K | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.12); catalogued as COSV99480165; called by muse, mutect2, varscan2
- PSG9 | c.829G>A p.G277S | Missense Mutation (SNP) | VAF 121/390 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.853); catalogued as rs1311205237, COSV52486471, COSV99392067; called by muse, mutect2, varscan2
- PTPN20 | c.295G>A p.E99K | Missense Mutation (SNP) | VAF 38/265 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.115); catalogued as rs1429335940; called by muse, mutect2, varscan2
- PTPRO | c.442A>G p.N148D | Missense Mutation (SNP) | VAF 28/138 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.629); catalogued as COSV99839780; called by muse, mutect2, varscan2
- RFLNB | c.241G>A p.E81K | Missense Mutation (SNP) | VAF 26/48 reads (54%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as rs370609692; called by muse, mutect2, varscan2
- RGS18 | c.184C>T p.R62C | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as rs767577887, COSV100817663, COSV100817920; called by muse, mutect2, varscan2
- RIPOR3 | c.2030T>C p.I677T | Missense Mutation (SNP) | VAF 14/189 reads (7%) | SIFT tolerated (0.2); PolyPhen benign (0.005); catalogued as rs566408535, COSV50414801; called by muse, mutect2
- RNF144A | c.397G>A p.V133M | Missense Mutation (SNP) | VAF 10/132 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs762999938; called by muse, mutect2
- RNF41 | c.79G>A p.E27K | Missense Mutation (SNP) | VAF 49/133 reads (37%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.747); catalogued as COSV100560130; called by muse, mutect2, varscan2
- RPE65 | c.1504C>T p.L502F | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99253623; called by muse, mutect2, varscan2
- RTN1 | c.2027C>T p.T676M | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as rs201164896; called by muse, mutect2, varscan2
- SCAF4 | c.203C>G p.S68* | Nonsense Mutation (SNP) | VAF 19/59 reads (32%) | catalogued as COSV99740945; called by muse, mutect2, varscan2
- SCN5A | c.4499A>C p.K1500T (on ENST00000333535 / NM_198056.3; = p.K1499T on NM_000335.5) | Missense Mutation (SNP) | VAF 34/64 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV61121873; called by muse, mutect2, varscan2
- SDK1 | c.2960C>A p.S987Y | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101268804; called by muse, mutect2, varscan2
- SLC6A15 | c.256C>T p.R86* | Nonsense Mutation (SNP) | VAF 35/55 reads (64%) | catalogued as rs1425540176, COSV99880203; called by muse, mutect2, varscan2
- SLITRK1 | c.1067A>C p.K356T | Missense Mutation (SNP) | VAF 18/126 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as COSV65674240; called by muse, mutect2, varscan2
- SORL1 | c.3518C>T p.S1173F | Missense Mutation (SNP) | VAF 40/97 reads (41%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.543); catalogued as COSV99492925; called by muse, mutect2, varscan2
- SOS1 | c.806T>A p.M269K | Missense Mutation (SNP) | VAF 16/90 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.493); catalogued as CM070275, CM074570, COSV67674247, COSV67676625; called by muse, mutect2, varscan2
- SPAST | c.1151C>T p.P384L | Missense Mutation (SNP) | VAF 17/75 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100188317; called by muse, mutect2, varscan2
- ST18 | c.1544G>A p.R515H | Missense Mutation (SNP) | VAF 11/135 reads (8%) | SIFT tolerated (0.05); PolyPhen benign (0.003); catalogued as rs376716506; called by muse, mutect2
- SYCP1 | c.2806C>G p.L936V | Missense Mutation (SNP) | VAF 19/90 reads (21%) | SIFT tolerated (0.23); PolyPhen benign (0.06); catalogued as COSV101050768; called by muse, mutect2, varscan2
- TACR3 | c.832G>T p.E278* | Nonsense Mutation (SNP) | VAF 38/78 reads (49%) | catalogued as COSV100510113, COSV59201731; called by muse, mutect2, varscan2
- TEK | c.2125C>A p.Q709K | Missense Mutation (SNP) | VAF 38/87 reads (44%) | SIFT tolerated (0.28); PolyPhen benign (0.023); catalogued as COSV101193180; called by muse, mutect2, varscan2
- TENM2 | c.3397G>A p.G1133S (on ENST00000518659 / NM_001122679.2; = p.G901S on NM_001080428.3) | Missense Mutation (SNP) | VAF 12/22 reads (55%) | SIFT tolerated (0.26); PolyPhen benign (0.08); catalogued as rs761542211, COSV101317909; called by muse, mutect2, varscan2
- TESK2 | c.1078C>T p.R360C | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as rs372042663; called by muse, mutect2, varscan2
- THSD7B | c.2946C>A p.F982L | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as COSV99744864; called by muse, mutect2, varscan2
- TNXB | c.12200G>C p.R4067P (on ENST00000647633; = p.R3820P on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/166 reads (6%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.964); catalogued as rs765400545, COSV100925922, COSV100926460; called by muse, mutect2
- TRAK2 | c.919G>A p.E307K | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100216641; called by muse, mutect2, varscan2
- TRAK2 | c.794G>C p.R265T | Missense Mutation (SNP) | VAF 21/125 reads (17%) | SIFT tolerated (0.48); PolyPhen benign (0.013); catalogued as COSV60274005; called by muse, mutect2, varscan2
- TTN | c.95311G>A p.A31771T (on ENST00000591111; = p.A24347T on NM_003319.4) | Missense Mutation (SNP) | VAF 17/75 reads (23%) | PolyPhen benign (0.001); catalogued as rs778297512, COSV100595744; called by muse, mutect2, varscan2
- TTN | c.1600G>C p.E534Q | Missense Mutation (SNP) | VAF 4/33 reads (12%) | PolyPhen probably damaging (0.979); catalogued as COSV100595748, COSV60040658; called by muse, mutect2, varscan2
- UNC5C | c.2545C>T p.R849W | Missense Mutation (SNP) | VAF 31/237 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs897744414, COSV71658111, COSV71661421; called by muse, mutect2, varscan2
- UNC5D | c.1994C>T p.A665V | Missense Mutation (SNP) | VAF 25/111 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.121); catalogued as rs781317548, COSV54766380, COSV54783476, COSV54804437; called by muse, mutect2, varscan2
- VPS13C | c.1009C>G p.Q337E (on ENST00000644861 / NM_020821.3; = p.Q294E on NM_017684.5) | Missense Mutation (SNP) | VAF 21/96 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.033); catalogued as rs760175192, COSV51163861, COSV99827348; called by muse, mutect2, varscan2
- ZBTB6 | c.584C>T p.S195L | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as COSV101021940; called by muse, mutect2, varscan2
- ZNF165 | c.817G>A p.D273N | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as rs774158679, COSV101055804; called by muse, mutect2, varscan2
- ZNF180 | c.1786C>T p.Q596* | Nonsense Mutation (SNP) | VAF 29/130 reads (22%) | catalogued as COSV99659608; called by muse, varscan2
- ZNF180 | c.1741C>T p.Q581* | Nonsense Mutation (SNP) | VAF 22/122 reads (18%) | catalogued as COSV99659609; called by muse, varscan2
- ZNF180 | c.1450C>G p.Q484E | Missense Mutation (SNP) | VAF 15/105 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as COSV99659610; called by muse, mutect2, varscan2
- ZNF384 | c.1220A>G p.N407S (on ENST00000361959; = p.N346S on NM_133476.5) | Missense Mutation (SNP) | VAF 7/83 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.904); catalogued as rs1228668413, COSV100158200; called by muse, mutect2
- ZNF558 | c.931G>A p.V311I | Missense Mutation (SNP) | VAF 26/84 reads (31%) | SIFT tolerated (0.46); PolyPhen benign (0.003); catalogued as rs782463844, COSV56862513; called by muse, mutect2, varscan2
- ZNF559 | c.282C>G p.N94K | Missense Mutation (SNP) | VAF 20/77 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV100416417; called by muse, mutect2, varscan2
- ZSCAN20 | c.892C>T p.Q298* | Nonsense Mutation (SNP) | VAF 18/82 reads (22%) | catalogued as COSV100792494; called by muse, mutect2, varscan2
- CD2AP | c.1665_1679del p.S556_T560del | In Frame Del (DEL) | VAF 20/59 reads (34%) | called by mutect2, pindel, varscan2
- COL12A1 | c.1981dup p.S661Ffs*13 | Frame Shift Ins (INS) | VAF 17/54 reads (31%) | called by mutect2, pindel, varscan2
- INSRR | c.781_787del p.A261Rfs*68 | Frame Shift Del (DEL) | VAF 7/39 reads (18%) | called by mutect2, pindel
- MLLT6 | c.29dup p.C11Mfs*45 | Frame Shift Ins (INS) | VAF 32/115 reads (28%) | called by mutect2, pindel, varscan2
- PCDH12 | c.2032G>T p.E678* | Nonsense Mutation (SNP) | VAF 3/22 reads (14%) | called by muse, mutect2
- SLC38A7 | c.793_795del p.F265del | In Frame Del (DEL) | VAF 5/32 reads (16%) | called by mutect2, pindel
- TRPM4 | c.1487C>T p.A496V | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT tolerated (0.35); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ADA2 | c.1410G>A p.R470= (on ENST00000262607; = p.R229= on NM_177405.3) | Silent (SNP) | VAF 25/46 reads (54%) | catalogued as COSV99375744; called by muse, mutect2, varscan2
- AGMO | c.360C>G p.A120= | Silent (SNP) | VAF 19/188 reads (10%) | catalogued as COSV100693662; called by muse, mutect2, varscan2
- AKR1C1 | c.171T>C p.N57= | Silent (SNP) | VAF 8/69 reads (12%) | catalogued as rs763761256, COSV66499474; called by muse, mutect2
- ALPK1 | c.3012C>T p.P1004= | Silent (SNP) | VAF 18/99 reads (18%) | catalogued as rs772371704, COSV99453133; called by muse, mutect2, varscan2
- ARHGAP45 | c.570C>T p.F190= | Silent (SNP) | VAF 12/46 reads (26%) | catalogued as COSV100490434, COSV100491090; called by muse, mutect2, varscan2
- BOLL | c.231C>T p.F77= | Silent (SNP) | VAF 6/51 reads (12%) | catalogued as rs1338031666, COSV56573747; called by muse, mutect2
- C1GALT1 | c.966C>T p.L322= | Silent (SNP) | VAF 20/153 reads (13%) | catalogued as rs746319437, COSV56179975; called by muse, mutect2, varscan2
- CDH8 | c.1254T>C p.P418= | Silent (SNP) | VAF 9/61 reads (15%) | catalogued as rs760119610, COSV100179716, COSV54898945; called by muse, mutect2, varscan2
- CST8 | c.303T>G p.T101= | Silent (SNP) | VAF 11/135 reads (8%) | catalogued as rs770746688, COSV99849878; called by muse, mutect2
- DIRAS1 | c.432C>T p.C144= | Silent (SNP) | VAF 32/110 reads (29%) | catalogued as rs1391849282, COSV60214917; called by muse, mutect2, varscan2
- DNAJC16 | c.1053C>T p.D351= | Silent (SNP) | VAF 14/184 reads (8%) | catalogued as rs764328213, COSV65449494; called by muse, mutect2
- DPH1 | c.231G>A p.P77= | Silent (SNP) | VAF 14/112 reads (13%) | catalogued as rs368873433; called by muse, mutect2, varscan2
- FABP9 | c.189C>T p.I63= | Silent (SNP) | VAF 18/190 reads (9%) | catalogued as COSV100986917; called by muse, mutect2
- GABRG3 | c.543C>T p.D181= | Silent (SNP) | VAF 9/72 reads (13%) | catalogued as rs200252575, COSV61531497; called by muse, mutect2
- ICE2 | c.2307T>G p.V769= | Silent (SNP) | VAF 5/60 reads (8%) | catalogued as COSV99831303; called by muse, mutect2
- IKBIP | c.681G>A p.T227= | Silent (SNP) | VAF 21/36 reads (58%) | catalogued as rs771776387, COSV61082099; called by muse, mutect2, varscan2
- KRTAP21-1 | c.21C>A p.G7= | Silent (SNP) | VAF 61/202 reads (30%) | catalogued as COSV100624902; called by muse, mutect2, varscan2
- LINGO2 | c.513G>A p.R171= | Silent (SNP) | VAF 4/64 reads (6%) | catalogued as COSV100430181; called by muse, mutect2
- MCM3 | c.984C>G p.L328= (on ENST00000229854 / NM_001366374.2; = p.L318= on NM_002388.6 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 19/96 reads (20%) | catalogued as COSV100008590; called by muse, mutect2, varscan2
- NDC80 | c.546G>A p.V182= | Silent (SNP) | VAF 12/107 reads (11%) | catalogued as COSV99859455; called by muse, mutect2
- NPFFR2 | c.117C>T p.R39= | Silent (SNP) | VAF 8/37 reads (22%) | catalogued as COSV58148681; called by muse, mutect2, varscan2
- PRKG1 | c.1519C>T p.L507= | Silent (SNP) | VAF 17/105 reads (16%) | catalogued as rs1050128985, COSV64769478; called by muse, mutect2, varscan2
- PRRT3 | c.1005G>A p.P335= | Silent (SNP) | VAF 59/125 reads (47%) | catalogued as rs777304061, COSV99926354; called by muse, mutect2, varscan2
- SLCO5A1 | c.636C>T p.F212= | Silent (SNP) | VAF 7/21 reads (33%) | catalogued as rs1444328899, COSV52661345; called by muse, mutect2, varscan2
- SLITRK5 | c.1194C>A p.I398= | Silent (SNP) | VAF 12/72 reads (17%) | catalogued as COSV100280342, COSV61521915; called by muse, mutect2, varscan2
- SYNPO2 | c.1758T>C p.N586= | Silent (SNP) | VAF 10/105 reads (10%) | catalogued as COSV100204938; called by muse, mutect2
- TESK2 | c.1584C>A p.P528= | Silent (SNP) | VAF 54/151 reads (36%) | catalogued as COSV100517081; called by muse, mutect2, varscan2
- TRIM32 | c.1104A>T p.P368= | Silent (SNP) | VAF 9/77 reads (12%) | catalogued as COSV100524894; called by muse, mutect2, varscan2
- TRPA1 | c.192C>A p.T64= | Silent (SNP) | VAF 11/38 reads (29%) | catalogued as COSV100083252; called by muse, mutect2, varscan2
- TTN | c.41247G>A p.P13749= (on ENST00000591111; = p.P6325= on NM_003319.4) | Silent (SNP) | VAF 28/133 reads (21%) | catalogued as rs747163190, COSV59991097; ClinVar: likely benign; called by muse, mutect2, varscan2
- ZSCAN1 | c.702G>A p.V234= | Silent (SNP) | VAF 14/87 reads (16%) | catalogued as COSV99991366; called by muse, mutect2, varscan2
- OGFOD3 | c.824-1995C>T | Intron (SNP) | VAF 16/67 reads (24%) | catalogued as rs1338138803, COSV57340005; called by muse, mutect2, varscan2
- PRRC2A | c.112+221G>A | Intron (SNP) | VAF 16/147 reads (11%) | catalogued as rs780282278, COSV100784528; called by muse, mutect2, varscan2
- SSPOP | n.14702A>G | RNA (SNP) | VAF 22/62 reads (35%) | catalogued as rs569525128, COSV65131054; called by muse, mutect2
- ZNF658B | n.2531A>G | RNA (SNP) | VAF 14/111 reads (13%) | called by mutect2, varscan2
- ZNF658B | n.2530G>T | RNA (SNP) | VAF 14/113 reads (12%) | called by mutect2, varscan2
